Somatic mutation profile of tumor specimen TARGET-20-PASIEJ-09A (aliquot TARGET-20-PASIEJ-09A-02D) from TARGET case TARGET-20-PASIEJ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,686 days).
Specimen TARGET-20-PASIEJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46a82b39-db48-4c3b-9001-6b8db532f76d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASIEJ-14A (Bone Marrow Normal), aliquot TARGET-20-PASIEJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d9fc7c9-d37d-4e24-aec3-742ed1e83e7d

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC6A12 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs545194537; called by muse, mutect2, varscan2
- WT1 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 23/221 reads (10%) | catalogued as CM086016; called by muse, mutect2, varscan2
